Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FS, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FS-01A (Primary Tumor).

TSS Patient ID:

Case #: (DOB: Sex: Ethnicity (Race)

Cancer Sample

Diagnosis: Breast Cancer Histological description: Infiltrative lobular carcinoma

Date of Procurement: Anatomical Site: Right breast Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: OCT

Container: block Type of Procurement: surgery Grade: 2

T Stage: 1 N Stage: 0 M Stage: 0 Treatment: none

Treatment Details: n/a

Normal Sample

Anatomic Site: Blood Sample Type: Normal Type of Procurement: blood draw

Matrix: Blood Specimen Format: frozen Container: tube

Date of Procurement:

CQCF: carcinoma, infiltrating ductal, nos 8500/3
Path: carcinoma, infiltrating lobular, nos 8520/3
Site: breast, nos C50.9 lw 10/21/11

Path report shows tumor as lobular and CQCF states TCGA tumor is ductal. after email confirmation with TSS, TBS pathologist confirms histology of TCGA tumor to be 'ductal'.

10/26/11
L

Source: NCI Genomic Data Commons file a4d0b72c-3e18-421c-aa03-af2514ff9075 (TCGA-AN-A0FS.3CD1D537-29E4-479B-99FA-26D27E192948.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).